Somatic mutation profile of tumor specimen 0DLRHX from CCDI case PBBZUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (307 days).
Specimen 0DLRHX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea21c8a5-7080-46a1-98af-8aaa6a3c4c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f121f43a-b969-42c1-a041-d41a41b54139

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCSK5 | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 102/839 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs373649072; called by muse, mutect2, varscan2
- TMED5 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 46/673 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- CNOT7 | c.729+41G>T | Intron (SNP) | VAF 58/670 reads (9%) | catalogued as COSV100778535; called by muse, mutect2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
